CGCI case HTMCP-03-06-02442 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/26ae5588-92d6-4fad-b7a3-9a795a02c0ba

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Dead; Days to death: 722 days (2.0 years).

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 45.5 years (16,606 days); Year of diagnosis: 2017; AJCC clinical T: T1b2; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 722 days (2.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 139 days; Days to treatment end: 223 days; Number of cycles: 3; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 382 days (1.0 years); Days to treatment end: 414 days (1.1 years); Treatment dose: 50; Treatment outcome: Partial Response; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 545 days (1.5 years); Days to treatment end: 572 days (1.6 years); Treatment dose: 24; Treatment outcome: Progressive Disease; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2400; Treatment outcome: Progressive Disease; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 5000; Treatment outcome: Progressive Disease; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (5 entries)
- Days to follow up: -8 days; Disease response: With Tumor.
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 347 days; Disease response: With Tumor.
- Days to follow up: 722 days (2.0 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -3,423.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day -3,423: Risk factors: HIV/AIDS.
- Day -3,423: Comorbidities: HIV/AIDS.
- Day 0: Pregnancy outcome: Induced Abortion.
- Day 0: Weight: 71.6 kg; Height: 163 cm; BMI: 26.9; CD4 count: 949; Haart treatment indicator: Yes; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Day 0: Pregnancy outcome: Miscarriage.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02442-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02442-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 1; Total pregnancy count: 4; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2007; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 0949.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 2, Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: External beam radiation.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Paclitaxel +carboplatin; Pharma adjuvant cycles count: 03.
- Treatments, Treatment 2: Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 24; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2, Extranodal radiation field list: Extranodal radiation field: Pelvis.
- Treatments, Treatment 3: Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 50.
